Gene-level copy-number profile of tumor specimen TCGA-UD-AABZ-01A from TCGA case TCGA-UD-AABZ, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 46.3 years (16,913 days).
Specimen TCGA-UD-AABZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-MESO.084c17aa-4008-4b87-bed0-028f20d3ab50.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-UD-AABZ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4636dc13-c399-43e5-89e0-e2fc0cd76d10

Most common (modal) total copy number across autosomal genes: 6 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 60; copy number 2: 2,834; copy number 3: 12,161; copy number 4: 5,189; copy number 5: 10,943; copy number 6: 23,477; copy number 7: 677; copy number 8: 525; copy number 9: 2,961; copy number 10: 987; copy number 11: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-UD-AABZ-01A-12D-A39Q-01): tumor purity 0.67, ploidy 1.8, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:93,416,951–93,745,615, 2 genes (within-gene range 0–3): AL591519.1, AL356094.2.

Amplified relative to the modal value (total copy number ≥ 13, i.e. more than twice the modal value of 6; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 25. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
